Somatic mutation profile of tumor specimen TARGET-40-PAMLKS-01A (aliquot TARGET-40-PAMLKS-01A-01D) from TARGET case TARGET-40-PAMLKS, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 12.3 years (4,509 days).
Specimen TARGET-40-PAMLKS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 32414d70-108e-442f-b91a-00fdda6f9a52.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-PAMLKS-10A (Blood Derived Normal), aliquot TARGET-40-PAMLKS-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8f95f8fb-3471-4289-9731-84610510cffc

The open-access MAF lists 42 somatic variants for this specimen: 32 protein-altering or splice-affecting, 5 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 5, 3'UTR 3, Intron 2, Nonsense Mutation 2, Splice Site 1, Frame Shift Ins 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTL7B | c.376G>A p.V126M | Missense Mutation (SNP) | VAF 91/359 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.057); catalogued as rs747709934, COSV65926965; called by muse, mutect2, varscan2
- ARHGAP4 | c.2046G>T p.Q682H | Missense Mutation (SNP) | VAF 42/113 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.229); catalogued as rs1557102701; called by muse, mutect2, varscan2
- COL4A4 | c.5029C>T p.R1677C | Missense Mutation (SNP) | VAF 413/973 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs759631057, CM074108, COSV61629349; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HTR1A | c.1219T>A p.F407I | Missense Mutation (SNP) | VAF 345/470 reads (73%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV60500365; called by muse, mutect2, varscan2
- MAVS | c.128G>A p.R43Q | Missense Mutation (SNP) | VAF 70/378 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs759224829; called by muse, mutect2, varscan2
- MYH14 | c.4237C>T p.R1413W | Missense Mutation (SNP) | VAF 67/157 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1447952322; called by muse, mutect2, varscan2
- RGS14 | c.581G>A p.R194Q | Missense Mutation (SNP) | VAF 45/97 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.18); catalogued as COSV101281728; called by muse, mutect2, varscan2
- SGCZ | c.305C>T p.P102L | Missense Mutation (SNP) | VAF 55/103 reads (53%) | SIFT tolerated (0.05); PolyPhen benign (0.018); catalogued as COSV101167120; called by muse, mutect2, varscan2
- SMO | c.2081dup p.A695Cfs*122 | Frame Shift Ins (INS) | VAF 9/60 reads (15%) | catalogued as rs1258200617; called by mutect2, pindel, varscan2
- SYNE2 | c.5503C>T p.H1835Y | Missense Mutation (SNP) | VAF 29/175 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59947344; called by muse, mutect2, varscan2
- TPR | c.4729G>A p.E1577K | Missense Mutation (SNP) | VAF 84/238 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV66605042; called by muse, mutect2, varscan2
- TSPAN8 | c.302C>T p.A101V | Missense Mutation (SNP) | VAF 65/483 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0.109); catalogued as rs746311736, COSV56078552; called by muse, mutect2, varscan2
- AGAP6 | c.919G>T p.E307* (on ENST00000374056 / NM_001365867.1; = p.E330* on NM_001077665.2) | Nonsense Mutation (SNP) | VAF 170/968 reads (18%) | called by muse, mutect2, varscan2
- ANLN | c.2164-1G>T p.X722_splice | Splice Site (SNP) | VAF 19/86 reads (22%) | called by muse, mutect2
- APEH | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- APPL1 | c.1865C>A p.A622E | Missense Mutation (SNP) | VAF 36/131 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C3orf62 | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 61/333 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- CHRDL1 | c.1055G>T p.G352V (on ENST00000372045; = p.G358V on NM_145234.4) | Missense Mutation (SNP) | VAF 14/388 reads (4%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.81); called by muse, mutect2
- CMYA5 | c.5107T>A p.L1703M | Missense Mutation (SNP) | VAF 80/390 reads (21%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- COQ7 | c.610C>T p.Q204* | Nonsense Mutation (SNP) | VAF 36/148 reads (24%) | called by muse, mutect2, varscan2
- GPD1 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 169/485 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- ITSN1 | c.4279A>C p.K1427Q | Missense Mutation (SNP) | VAF 16/258 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.777); called by muse, mutect2
- LRRC3C | c.328C>A p.L110M | Missense Mutation (SNP) | VAF 55/306 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MGAM | c.4123C>A p.L1375I | Missense Mutation (SNP) | VAF 51/341 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- OSTM1 | c.769G>A p.D257N | Missense Mutation (SNP) | VAF 3117/3398 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- RYR2 | c.14770T>C p.Y4924H | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SMARCC2 | c.2394G>C p.E798D | Missense Mutation (SNP) | VAF 91/550 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMEM130 | c.329C>T p.T110I | Missense Mutation (SNP) | VAF 56/344 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TRPM1 | c.675G>C p.K225N | Missense Mutation (SNP) | VAF 81/488 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- TTN | c.65133A>C p.R21711S (on ENST00000591111; = p.R14287S on NM_003319.4) | Missense Mutation (SNP) | VAF 125/605 reads (21%) | PolyPhen benign (0.306); called by muse, mutect2, varscan2
- UGT1A5 | c.636G>T p.K212N | Missense Mutation (SNP) | VAF 221/613 reads (36%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- ZBTB20 | c.2131G>A p.E711K (on ENST00000474710 / NM_001164342.2; = p.E638K on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 62/301 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- AC010522.1 | c.195A>C p.A65= | Silent (SNP) | VAF 54/271 reads (20%) | called by muse, mutect2, varscan2
- COL5A1 | c.597C>T p.I199= | Silent (SNP) | VAF 29/97 reads (30%) | catalogued as rs147008954; ClinVar: likely benign; called by muse, mutect2, varscan2
- GPAT4 | c.1095A>G p.K365= | Silent (SNP) | VAF 138/824 reads (17%) | called by muse, mutect2, varscan2
- SEMG2 | c.552T>G p.G184= | Silent (SNP) | VAF 255/436 reads (58%) | called by muse, mutect2, varscan2
- TAF1 | c.2796G>T p.G932= (on ENST00000373790 / NM_138923.4; = p.G953= on NM_004606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 107/303 reads (35%) | called by muse, mutect2, varscan2
- CDC27 | c.*2391A>T | 3'UTR (SNP) | VAF 24/153 reads (16%) | called by muse, mutect2, varscan2
- DOCK9 | c.*18A>G | 3'UTR (SNP) | VAF 346/624 reads (55%) | catalogued as rs182904172; called by muse, mutect2, varscan2
- EMD | c.266-29C>A | Intron (SNP) | VAF 74/216 reads (34%) | catalogued as rs782704523; called by muse, mutect2, varscan2
- H4-16 | c.*34G>C | 3'UTR (SNP) | VAF 122/223 reads (55%) | called by muse, mutect2, varscan2
- HNRNPK | c.1362-322G>A | Intron (SNP) | VAF 12/32 reads (38%) | called by muse, mutect2, varscan2
